Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1DB, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1DB-01A (Primary Tumor).

100-0-3
Adenocarcinoma, NOS 8140/3
Site Code: Sigmoid colon C18.7

1/10/11
lw

h (First Tumor)

Tumor Site:	Sigmoid Distal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	Lymphoid Aggregates
Crohn's like reaction	☐ None ☒ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☒ Expansile ☐ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	1.4
Pathologist Comment:	No normal mucosa - only

HI/AA Discrepancy		

Source: NCI Genomic Data Commons file 520dbc77-c326-4d0f-8591-5ca72899a358 (TCGA-DM-A1DB.71808664-82BA-4B65-B719-C54176F69ABF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).